Gene-level copy-number profile of tumor specimen TCGA-2Z-A9J6-01A from TCGA case TCGA-2Z-A9J6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.0 years (22,265 days).
Specimen TCGA-2Z-A9J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.5097e644-4860-4a56-ab46-08a7ac5e6912.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9J6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adb23195-5eaf-4542-aea1-59dcb6a7d2d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,522; copy number 2: 41,272; copy number 3: 15,002; copy number 4: 18; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9J6-01A-11D-A381-01): tumor purity 0.76, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:114,077,133–114,241,770, 5 genes, copy number 5: AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459.

Autosomal genes at a single copy (total copy number 1): 1,101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
